Somatic mutation profile of tumor specimen TCGA-28-1749-01A (aliquot TCGA-28-1749-01A-01W-0643-08) from TCGA case TCGA-28-1749, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 73.3 years (26,765 days).
Specimen TCGA-28-1749-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18526e7a-dc0f-4520-affa-fcf4c5178ca3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-1749-10A (Blood Derived Normal), aliquot TCGA-28-1749-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a93ab83-8ce8-4a84-97d2-b7e365fcc227

The open-access MAF lists 48 somatic variants for this specimen: 35 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 11, Frame Shift Del 3, Splice Site 3, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1088C>T p.T363I | Missense Mutation (SNP) | VAF 1376/5815 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1164954595, COSV51779091, COSV51843270; called by muse, mutect2, varscan2
- PTEN | c.68del p.L23* | Frame Shift Del (DEL) | VAF 39/61 reads (64%) | catalogued as rs1554890400, CM1513153, COSV64299703; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AL592490.1 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.815); catalogued as rs781466949, COSV69424350, COSV69427254; called by muse, mutect2, varscan2
- ALCAM | c.1103A>C p.K368T | Missense Mutation (SNP) | VAF 206/419 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100064520; called by muse, mutect2, varscan2
- ANO4 | c.2804G>A p.R935H (on ENST00000392977 / NM_001286615.2; = p.R900H on NM_178826.4) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs143188971; called by muse, mutect2, varscan2
- ATP8A2 | c.1057+2T>A p.X353_splice | Splice Site (SNP) | VAF 326/800 reads (41%) | catalogued as COSV99681004; called by muse, mutect2
- CCBE1 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs550643166, COSV101232800; called by muse, mutect2, varscan2
- CHIA | c.1095T>A p.D365E (on ENST00000343320; = p.D257E on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 136/327 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100588617; called by muse, mutect2, varscan2
- CLEC10A | c.622T>G p.Y208D (on ENST00000254868 / NM_182906.4; = p.Y184D on NM_006344.4) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99644628; called by muse, mutect2, varscan2
- DCLRE1A | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 67/90 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100800281; called by muse, mutect2, varscan2
- DNAH11 | c.3911G>A p.R1304H | Missense Mutation (SNP) | VAF 140/579 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs369475751; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPP6 | c.1556C>T p.T519M (on ENST00000377770 / NM_001364500.2; = p.T457M on NM_001936.5) | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs373181078, COSV59650839; called by muse, mutect2, varscan2
- EDIL3 | c.121T>A p.L41M | Missense Mutation (SNP) | VAF 17/270 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV99675500; called by muse, mutect2
- ERCC2 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs139884931; called by muse, mutect2, varscan2
- FAM47B | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 60/71 reads (85%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as rs1459885438, COSV100264201; called by muse, mutect2, varscan2
- FLG2 | c.4541C>G p.S1514W | Missense Mutation (SNP) | VAF 188/440 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV66173804; called by muse, mutect2, varscan2
- INTS7 | c.1470G>T p.L490= | Splice Region (SNP) | VAF 15/454 reads (3%) | catalogued as COSV65344935; called by muse, mutect2
- KIF2B | c.989C>A p.A330D | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV99274987; called by muse, mutect2, varscan2
- KLK15 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.753); catalogued as rs754657461, COSV56826136; called by muse, mutect2, varscan2
- MMP27 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99498335; called by muse, mutect2
- MSR1 | c.749T>C p.I250T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV100026838; called by muse, mutect2, varscan2
- MX1 | c.1131+1G>A p.X377_splice | Splice Site (SNP) | VAF 24/58 reads (41%) | catalogued as COSV99912520; called by muse, mutect2, varscan2
- MYH4 | c.4307T>C p.V1436A | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as COSV99700695; called by muse, mutect2
- NUP85 | c.158T>G p.F53C | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.312); catalogued as COSV99823077; called by muse, mutect2, varscan2
- OR2T11 | c.518A>T p.H173L | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100424736; called by muse, mutect2, varscan2
- OR51T1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 126/316 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV100434355; called by muse, mutect2, varscan2
- PAX4 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs747805740, COSV58389181; called by muse, mutect2, varscan2
- SCYL1 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs771810546, COSV54216959; called by muse, mutect2, varscan2
- SGPL1 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100940318; called by muse, mutect2
- SLC7A13 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs377120069; called by muse, mutect2
- SNUPN | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.576); catalogued as rs377184433; called by muse, mutect2, varscan2
- SPI1 | c.330+2T>A p.X110_splice | Splice Site (SNP) | VAF 13/33 reads (39%) | catalogued as COSV99908762; called by muse, mutect2, varscan2
- TBXAS1 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV54937591; called by muse, mutect2, varscan2
- ACACA | c.731del p.A244Vfs*17 | Frame Shift Del (DEL) | VAF 97/301 reads (32%) | called by mutect2, pindel, varscan2
- FRRS1 | c.81del p.V28* | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | called by mutect2, pindel, varscan2
- ALDH1A3 | c.1275C>T p.I425= | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as rs1047087988, COSV100320298; called by muse, mutect2, varscan2
- CSMD2 | c.7488C>T p.N2496= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs765627105, COSV53966778; called by muse, mutect2, varscan2
- DSG3 | c.1026C>T p.S342= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs555118940, COSV99933955; called by muse, mutect2, varscan2
- HMCN1 | c.12804C>T p.D4268= | Silent (SNP) | VAF 103/245 reads (42%) | catalogued as rs147822137, COSV54932998; called by muse, mutect2, varscan2
- KDR | c.1311C>T p.Y437= | Silent (SNP) | VAF 488/1129 reads (43%) | catalogued as rs139884656; called by muse, mutect2, varscan2
- LHX8 | c.945C>T p.Y315= | Silent (SNP) | VAF 38/222 reads (17%) | catalogued as rs370428970; called by muse, mutect2, varscan2
- OBSCN | c.4944C>T p.C1648= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs370563598; called by muse, mutect2, varscan2
- PMS2 | c.267A>G p.T89= | Silent (SNP) | VAF 103/319 reads (32%) | catalogued as rs876659181, COSV99764038; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRDM9 | c.2610C>T p.S870= | Silent (SNP) | VAF 176/503 reads (35%) | catalogued as rs1189953454, COSV99690106; called by muse, varscan2
- RPTN | c.1920C>T p.D640= | Silent (SNP) | VAF 110/253 reads (43%) | catalogued as COSV100285361; called by muse, mutect2, varscan2
- SLC4A10 | c.1482T>G p.A494= (on ENST00000446997 / NM_001354461.2; = p.A464= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 74/178 reads (42%) | catalogued as COSV99763105; called by muse, mutect2, varscan2
- MIR541 | n.2C>T | RNA (SNP) | VAF 9/64 reads (14%) | catalogued as rs559168393; called by muse, mutect2, varscan2
- RPL26P30 | n.909A>C | RNA (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2
